HCMI case HCM-BROD-1105-C73 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Thyroid gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/149eef24-418a-4f5e-b32e-060a8baa8322

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1941; Vital status: Dead; Days to death: 7,635 days (20.9 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Papillary carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8050/3; ICD-10 code: C73.9; Tissue or organ of origin: Thyroid gland; Classification of tumor: primary; Age at diagnosis: 54.2 years (19,803 days); Metastasis at diagnosis: Metastasis, NOS; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 7,546 days (20.7 years); Days to treatment end: 7,627 days (20.9 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Metastasis of the thyroid gland (histology not recorded by GDC). ICD-10 code: C78.6; Site of resection or biopsy: Pleura, NOS; Age at diagnosis: 54.2 years (19,803 days).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Lenvatinib + Sorafenib; Treatment intent type: Maintenance Therapy; Days to treatment start: 7,151 days (19.6 years); Days to treatment end: 7,288 days (20.0 years); Treatment outcome: Progressive Disease.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 7,635 days (20.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 46 kg; Height: 160 cm; BMI: 18.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (1 sample)
- Sample HCM-BROD-1105-C73-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 18.
